Somatic mutation profile of tumor specimen TARGET-20-PARPPY-03A (aliquot TARGET-20-PARPPY-03A-01D) from TARGET case TARGET-20-PARPPY, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.3 years (3,044 days).
Specimen TARGET-20-PARPPY-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d93abeab-f2dd-4a96-8934-b41c6131b264.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARPPY-14A (Bone Marrow Normal), aliquot TARGET-20-PARPPY-14A-02D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99feefa6-f158-4352-9ca5-83430ef56f38

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1210C>T p.R404* | Nonsense Mutation (SNP) | VAF 55/202 reads (27%) | catalogued as rs373145711, CM116006, COSV60102210; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KIT | c.2458G>T p.D820Y | Missense Mutation (SNP) | VAF 8/182 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519710, CM023092, COSV55387253, COSV55397865, COSV55435132; ClinVar: pathogenic; called by muse, mutect2
- SALL1 | c.3448C>A p.Q1150K | Missense Mutation (SNP) | VAF 14/203 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); called by muse, mutect2
- STOX2 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 13/259 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2
- SUPT5H | c.1955_1956insGGCAGGAGG p.R652_D653insAGG | In Frame Ins (INS) | VAF 21/98 reads (21%) | called by mutect2, pindel, varscan2
- PPP6R3 | c.2451-309G>A | Intron (SNP) | VAF 10/313 reads (3%) | called by muse, mutect2
